Somatic mutation profile of tumor specimen 0DVZEJ from CCDI case PBCNEY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 16.1 years (5,898 days).
Specimen 0DVZEJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8918c9b6-3db8-458f-a58b-f98fc597a63f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVZED (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8d31e08-d811-4249-9d36-f035f2a24db9

The open-access MAF lists 120 somatic variants for this specimen: 70 protein-altering or splice-affecting, 30 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 30, Intron 9, 3'UTR 6, Splice Region 3, Splice Site 2, 5'UTR 2, 5'Flank 2, Frame Shift Ins 1, Frame Shift Del 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA2 | c.365C>T p.T122M (on ENST00000614293; = p.T92M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs746381652, COSV55805666; called by muse, mutect2, varscan2
- ABCB8 | c.950G>T p.R317L (on ENST00000297504 / NM_001282291.2; = p.R300L on NM_007188.5) | Missense Mutation (SNP) | VAF 78/390 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754096279; called by muse, mutect2, varscan2
- ADGRB3 | c.312G>T p.K104N | Missense Mutation (SNP) | VAF 215/613 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs764728357; called by mutect2, varscan2
- C20orf144 | c.346C>G p.L116V | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV55779165; called by muse, mutect2
- CACNA2D3 | c.1157C>G p.P386R | Missense Mutation (SNP) | VAF 16/498 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV55550051; called by muse, mutect2
- COL6A5 | c.4877T>G p.L1626W | Missense Mutation (SNP) | VAF 110/632 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs1201891949; called by mutect2, varscan2
- CR589904.2 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 126/1238 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.034); catalogued as rs951809123; called by muse, mutect2
- CTNNB1 | c.1324G>A p.G442S | Missense Mutation (SNP) | VAF 71/414 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.685); catalogued as rs1299004124; called by muse, mutect2, varscan2
- CYP11B2 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 122/650 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1311444460, COSV100011482; ClinVar: uncertain significance; called by muse, varscan2
- DDX60L | c.3605C>T p.T1202M | Missense Mutation (SNP) | VAF 71/607 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs371499006; called by muse, mutect2, varscan2
- DTX2 | c.850C>G p.L284V | Missense Mutation (SNP) | VAF 38/496 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.199); catalogued as rs746479588; called by muse, mutect2
- FAM210A | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 250/625 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs1433578965; called by muse, mutect2, varscan2
- KIAA1217 | c.3563G>A p.R1188Q | Missense Mutation (SNP) | VAF 56/852 reads (7%) | SIFT tolerated (0.75); PolyPhen benign (0.011); catalogued as rs766557108, COSV56814580; called by muse, mutect2
- KLRC1 | c.572G>C p.G191A | Missense Mutation (SNP) | VAF 169/1160 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as COSV61726199; called by muse, mutect2, varscan2
- MAB21L4 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 51/276 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs201848788; called by muse, mutect2, varscan2
- NBEAL2 | c.406C>G p.L136V | Missense Mutation (SNP) | VAF 40/444 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as COSV99434998; called by muse, mutect2
- NDST4 | c.881A>G p.K294R | Missense Mutation (SNP) | VAF 79/654 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.029); catalogued as rs1160059134; called by muse, mutect2, varscan2
- NECAP1 | c.21C>G p.Y7* | Nonsense Mutation (SNP) | VAF 56/407 reads (14%) | catalogued as rs752149350, COSV60250344; called by muse, mutect2, varscan2
- NFYB | c.62A>G p.Y21C | Missense Mutation (SNP) | VAF 95/811 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as rs1438476529; called by muse, mutect2, varscan2
- OR52E2 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 90/869 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.466); catalogued as rs201289601; called by muse, mutect2, varscan2
- PDCD7 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as rs1195506923; called by muse, mutect2, varscan2
- SLITRK3 | c.2152G>A p.G718R | Missense Mutation (SNP) | VAF 111/693 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.05); catalogued as rs1187928560, COSV53845526; called by muse, mutect2, varscan2
- SOCS5 | c.427G>T p.G143C | Missense Mutation (SNP) | VAF 118/838 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV60605045; called by muse, mutect2, varscan2
- SORCS3 | c.2431G>T p.A811S | Missense Mutation (SNP) | VAF 51/998 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.866); catalogued as COSV63793290; called by muse, mutect2
- SP110 | c.669G>A p.V223= | Splice Region (SNP) | VAF 60/410 reads (15%) | catalogued as rs376677600; called by muse, mutect2, varscan2
- SPECC1 | c.2426C>G p.T809R | Missense Mutation (SNP) | VAF 128/645 reads (20%) | SIFT tolerated (0.94); PolyPhen benign (0.011); catalogued as COSV54952850; called by muse, mutect2, varscan2
- TM7SF3 | c.1163C>T p.S388L | Missense Mutation (SNP) | VAF 78/1284 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as rs749478217; called by muse, mutect2
- UNC79 | c.5468G>T p.G1823V (on ENST00000393151 / NM_001346218.2; = p.G1646V on NM_020818.5) | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.284); catalogued as COSV56417086; called by muse, mutect2, varscan2
- ADAMTS19 | c.2744G>T p.S915I | Missense Mutation (SNP) | VAF 124/1580 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.049); called by muse, mutect2
- ADTRP | c.507C>T p.R169= | Splice Region (SNP) | VAF 103/820 reads (13%) | called by muse, mutect2, varscan2
- AFTPH | c.2017dup p.T673Nfs*22 | Frame Shift Ins (INS) | VAF 156/968 reads (16%) | called by mutect2, varscan2
- AL662899.2 | c.210C>G p.D70E | Missense Mutation (SNP) | VAF 236/691 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- CACNB4 | c.1517G>T p.R506L | Missense Mutation (SNP) | VAF 112/728 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CDH23 | c.6926C>A p.A2309D | Missense Mutation (SNP) | VAF 70/463 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CNR1 | c.718A>G p.M240V | Missense Mutation (SNP) | VAF 47/287 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- CNTRL | c.1028C>G p.T343R | Missense Mutation (SNP) | VAF 95/400 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- DACT3 | c.1136C>T p.P379L | Missense Mutation (SNP) | VAF 44/285 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DMXL1 | c.4060G>T p.A1354S | Missense Mutation (SNP) | VAF 124/1074 reads (12%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- DUSP22 | c.410A>G p.E137G | Missense Mutation (SNP) | VAF 116/1545 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2
- FAM174A | c.124G>C p.G42R | Missense Mutation (SNP) | VAF 97/663 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- FAT3 | c.12912G>T p.K4304N | Missense Mutation (SNP) | VAF 72/956 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FLACC1 | c.1009C>A p.Q337K | Missense Mutation (SNP) | VAF 162/847 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- FYN | c.1575del p.A526Rfs*32 | Frame Shift Del (DEL) | VAF 78/740 reads (11%) | called by mutect2, varscan2
- GBP5 | c.323A>T p.D108V | Missense Mutation (SNP) | VAF 120/451 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GBP6 | c.208A>G p.T70A | Missense Mutation (SNP) | VAF 53/207 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- GUCY2D | c.512C>A p.A171D | Missense Mutation (SNP) | VAF 82/160 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- HDAC9 | c.2866C>A p.H956N | Missense Mutation (SNP) | VAF 287/734 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HPDL | c.718C>G p.R240G | Missense Mutation (SNP) | VAF 85/321 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSPB9 | c.355C>A p.L119M | Missense Mutation (SNP) | VAF 31/248 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- KCNK15 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 23/239 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.877); called by muse, mutect2
- KLRG1 | c.332T>A p.L111H | Missense Mutation (SNP) | VAF 98/928 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LANCL2 | c.932G>T p.S311I | Missense Mutation (SNP) | VAF 242/553 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- LHX4 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 75/473 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LYSMD4 | c.552A>C p.E184D (on ENST00000409796 / NM_001284417.2; = p.E185D on NM_152449.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/221 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- PCDHB3 | c.1673C>T p.S558L | Missense Mutation (SNP) | VAF 34/299 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- PCIF1 | c.911C>A p.A304E | Missense Mutation (SNP) | VAF 137/714 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- PIK3C2G | c.1878A>C p.K626N (on ENST00000676171; = p.K585N on NM_004570.5) | Missense Mutation (SNP) | VAF 44/890 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.624); called by muse, mutect2
- PPFIA3 | c.240+3C>A | Splice Region (SNP) | VAF 34/276 reads (12%) | called by muse, mutect2, varscan2
- PRRC2A | c.2798G>A p.S933N | Missense Mutation (SNP) | VAF 25/366 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- RFX5 | c.1255A>G p.I419V | Missense Mutation (SNP) | VAF 51/346 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- SDCCAG8 | c.964G>C p.V322L | Missense Mutation (SNP) | VAF 132/660 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- SH3D19 | c.695-1G>A p.X232_splice | Splice Site (SNP) | VAF 58/517 reads (11%) | called by muse, mutect2, varscan2
- SLC26A5 | c.1311+2T>C p.X437_splice | Splice Site (SNP) | VAF 53/735 reads (7%) | called by muse, mutect2
- SNX29 | c.2135T>C p.V712A | Missense Mutation (SNP) | VAF 86/506 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- SPIRE1 | c.1945G>C p.G649R (on ENST00000409402 / NM_001128626.2; = p.G635R on NM_020148.3) | Missense Mutation (SNP) | VAF 22/856 reads (3%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.77); called by muse, mutect2
- TENT4A | c.1625T>G p.I542S | Missense Mutation (SNP) | VAF 140/1797 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- TTN | c.79883T>A p.V26628E (on ENST00000591111; = p.V19204E on NM_003319.4) | Missense Mutation (SNP) | VAF 77/1068 reads (7%) | PolyPhen probably damaging (0.998); called by muse, mutect2
- VPS13D | c.129G>T p.K43N | Missense Mutation (SNP) | VAF 175/695 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 32/530 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- ZNF862 | c.466C>A p.Q156K | Missense Mutation (SNP) | VAF 22/692 reads (3%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2
- ARHGAP39 | c.165G>A p.P55= | Silent (SNP) | VAF 87/377 reads (23%) | catalogued as rs759315006; called by muse, mutect2, varscan2
- ASB15 | c.1023C>T p.H341= | Silent (SNP) | VAF 55/639 reads (9%) | called by muse, mutect2
- C11orf53 | c.420G>A p.P140= | Silent (SNP) | VAF 93/510 reads (18%) | catalogued as COSV54721551; called by muse, mutect2, varscan2
- DCAF4L2 | c.276C>A p.V92= | Silent (SNP) | VAF 165/628 reads (26%) | catalogued as rs1022730204, COSV60477047; called by muse, mutect2, varscan2
- DTD1 | c.33C>T p.A11= | Silent (SNP) | VAF 19/179 reads (11%) | catalogued as rs1197367271; called by muse, mutect2, varscan2
- FMN2 | c.1305G>A p.Q435= | Silent (SNP) | VAF 28/344 reads (8%) | catalogued as rs767117704, COSV60445424; called by muse, mutect2
- FOXB2 | c.1134G>T p.L378= | Silent (SNP) | VAF 47/126 reads (37%) | called by muse, mutect2, varscan2
- GALNT6 | c.432C>A p.A144= | Silent (SNP) | VAF 110/918 reads (12%) | called by muse, mutect2, varscan2
- GM2A | c.216C>A p.T72= | Silent (SNP) | VAF 138/1363 reads (10%) | called by muse, mutect2
- HMGCR | c.432C>A p.A144= | Silent (SNP) | VAF 118/1596 reads (7%) | called by muse, mutect2
- HMGXB3 | c.3318G>T p.L1106= (on ENST00000613459; = p.L860= on NM_014983.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 114/1127 reads (10%) | called by muse, mutect2, varscan2
- IRAG1 | c.1281C>G p.G427= | Silent (SNP) | VAF 198/431 reads (46%) | called by muse, mutect2, varscan2
- ITK | c.63T>G p.T21= | Silent (SNP) | VAF 160/1075 reads (15%) | catalogued as COSV70065410; called by muse, mutect2, varscan2
- ITLN2 | c.267C>A p.G89= | Silent (SNP) | VAF 115/1497 reads (8%) | catalogued as rs768368673; called by muse, mutect2
- MYCBP2 | c.1698C>T p.F566= (on ENST00000357337; = p.F604= on NM_015057.5) | Silent (SNP) | VAF 64/792 reads (8%) | catalogued as COSV62013484; called by muse, mutect2
- MYH10 | c.5181G>T p.L1727= | Silent (SNP) | VAF 48/326 reads (15%) | called by muse, mutect2, varscan2
- NOBOX | c.699G>T p.V233= | Silent (SNP) | VAF 21/207 reads (10%) | catalogued as rs775645061; called by muse, mutect2, varscan2
- NYAP2 | c.804C>T p.Y268= | Silent (SNP) | VAF 63/328 reads (19%) | catalogued as rs746382288, COSV55997949; called by muse, mutect2, varscan2
- OR1E1 | c.153G>T p.L51= | Silent (SNP) | VAF 189/703 reads (27%) | called by muse, mutect2
- PDE11A | c.411C>T p.Y137= | Silent (SNP) | VAF 94/649 reads (14%) | catalogued as COSV53696120; called by muse, mutect2, varscan2
- PNPLA4 | c.210C>T p.A70= | Silent (SNP) | VAF 169/401 reads (42%) | catalogued as rs199502967; called by muse, mutect2, varscan2
- STRA8 | c.717C>A p.V239= (on ENST00000275764; = p.V217= on NM_182489.2) | Silent (SNP) | VAF 70/280 reads (25%) | called by muse, mutect2, varscan2
- SUGP1 | c.1482C>A p.G494= | Silent (SNP) | VAF 51/413 reads (12%) | called by muse, mutect2, varscan2
- TRAK1 | c.804G>A p.E268= (on ENST00000327628 / NM_001349247.2; = p.E210= on NM_014965.5) | Silent (SNP) | VAF 52/625 reads (8%) | catalogued as COSV58259063; called by muse, mutect2
- TTYH1 | c.648C>T p.A216= | Silent (SNP) | VAF 63/288 reads (22%) | called by muse, mutect2, varscan2
- UBE2C | c.264C>A p.G88= | Silent (SNP) | VAF 80/508 reads (16%) | called by muse, mutect2, varscan2
- UGT1A3 | c.126C>A p.L42= | Silent (SNP) | VAF 57/586 reads (10%) | called by muse, mutect2
- WDR27 | c.513C>A p.V171= | Silent (SNP) | VAF 270/1181 reads (23%) | called by muse, mutect2, varscan2
- ZKSCAN5 | c.1056C>A p.G352= | Silent (SNP) | VAF 29/271 reads (11%) | catalogued as COSV58744759; called by muse, mutect2, varscan2
- ZNF174 | c.1206A>T p.R402= | Silent (SNP) | VAF 49/234 reads (21%) | called by muse, mutect2, varscan2
- AP2M1 | c.1173+39G>T | Intron (SNP) | VAF 38/239 reads (16%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 10/215 reads (5%) | called by muse, mutect2
- CD300LD | chr17:74592309 C>A | 5'Flank (SNP) | VAF 145/748 reads (19%) | called by muse, mutect2, varscan2
- CD86 | c.*92A>C | 3'UTR (SNP) | VAF 7/117 reads (6%) | called by muse, mutect2
- CFAP54 | c.8281+15C>T | Intron (SNP) | VAF 75/654 reads (11%) | called by muse, mutect2, varscan2
- GTF2F1 | chr19:6396435 A>G | 5'Flank (SNP) | VAF 64/539 reads (12%) | called by mutect2, varscan2
- ITGA4 | c.2074-27A>G | Intron (SNP) | VAF 52/459 reads (11%) | called by muse, mutect2, varscan2
- KCNC4 | c.*516A>C | 3'UTR (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2
- PDZRN3 | c.*29G>T | 3'UTR (SNP) | VAF 31/211 reads (15%) | called by muse, mutect2, varscan2
- PROB1 | c.-23A>T | 5'UTR (SNP) | VAF 18/120 reads (15%) | catalogued as rs1215681182; called by muse, mutect2, varscan2
- SLC13A5 | c.*63C>A | 3'UTR (SNP) | VAF 21/186 reads (11%) | called by muse, mutect2, varscan2
- SLC50A1 | c.*23C>A | 3'UTR (SNP) | VAF 18/238 reads (8%) | called by muse, mutect2
- SMIM23 | c.434+34C>A | Intron (SNP) | VAF 97/743 reads (13%) | called by muse, mutect2, varscan2
- SNHG14 | n.5099C>G | RNA (SNP) | VAF 60/164 reads (37%) | called by muse, mutect2, varscan2
- STK31 | c.50+68G>A | Intron (SNP) | VAF 7/62 reads (11%) | catalogued as rs1268748321; called by muse, mutect2, varscan2
- TAF1C | c.1387-38C>A | Intron (SNP) | VAF 33/117 reads (28%) | called by muse, mutect2, varscan2
- THAP1 | c.-6G>A | 5'UTR (SNP) | VAF 72/310 reads (23%) | catalogued as rs753670048; called by muse, mutect2, varscan2
- TMEM131 | c.5011+51G>C | Intron (SNP) | VAF 58/538 reads (11%) | called by muse, mutect2, varscan2
- UGT2B7 | c.*65A>T | 3'UTR (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- VAV1 | c.1778-61C>A | Intron (SNP) | VAF 11/170 reads (6%) | called by muse, mutect2
